Somatic mutation profile of tumor specimen TCGA-CK-5916-01A (aliquot TCGA-CK-5916-01A-11D-1650-10) from TCGA case TCGA-CK-5916, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 71.2 years (26,024 days).
Specimen TCGA-CK-5916-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc0ee0c1-ae6c-45d7-b026-c25c4a0ef171.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-5916-10A (Blood Derived Normal), aliquot TCGA-CK-5916-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a935891f-709b-433d-942a-f6f04b17ff0a

The open-access MAF lists 1,739 somatic variants for this specimen: 1,307 protein-altering or splice-affecting, 392 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 898, Silent 392, Frame Shift Del 261, Frame Shift Ins 57, Nonsense Mutation 44, Intron 22, In Frame Del 18, Splice Region 16, Splice Site 12, RNA 6, 5'UTR 4, 3'UTR 3.

Variants (750 of 1,739; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 41/154 reads (27%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CAPN3 | c.1795dup p.T599Nfs*33 | Frame Shift Ins (INS) | VAF 44/190 reads (23%) | catalogued as rs80338803; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- COL6A1 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121912938, CM050214, CM1310878, COSV62612600; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CRYBA1 | c.500+1G>A p.X167_splice | Splice Site (SNP) | VAF 27/87 reads (31%) | catalogued as rs775038545, COSV99837096; ClinVar: likely pathogenic; called by muse, mutect2
- DMD | c.10453del p.L3485* | Frame Shift Del (DEL) | VAF 63/291 reads (22%) | catalogued as rs886043375, CD073610; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- IDS | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs113993949, CM960855, CM981013, HM971760, COSV100558243; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IRAK4 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 94/315 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377584435, CM078314; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1265del p.K422Sfs*10 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as rs397508083; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KCNQ2 | c.1627G>A p.V543M (on ENST00000359125 / NM_172107.4; = p.V515M on NM_004518.6) | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs794727134, COSV60554922; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NEXMIF | c.1123del p.E375Rfs*21 | Frame Shift Del (DEL) | VAF 58/207 reads (28%) | catalogued as rs886041774, COSV50024533, COSV50087046, COSV99280656; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- OTOGL | c.5449C>T p.R1817* (on ENST00000547103; = p.R1808* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 60/186 reads (32%) | catalogued as rs768620276, CM134337, COSV54024520; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RUNX2 | c.90del p.S31Pfs*9 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs397515538; ClinVar: pathogenic; called by pindel, varscan2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 21/68 reads (31%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TCF20 | c.1707del p.R570Dfs*37 | Frame Shift Del (DEL) | VAF 25/54 reads (46%) | catalogued as rs1555926655; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 47/132 reads (36%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.497A>G p.N166S | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV55299203; called by muse, mutect2, varscan2
- AAK1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 97/335 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755622582, COSV68646845; called by muse, mutect2, varscan2
- AASDH | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401606710, COSV52711026; called by muse, mutect2, varscan2
- ABCA1 | c.6019G>A p.V2007M | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs536836332, COSV66071176; called by muse, mutect2, varscan2
- ABCA13 | c.10657G>A p.A3553T | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1327931619, COSV71295260; called by muse, mutect2, varscan2
- ABCA4 | c.6345C>A p.S2115R | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV64678659; called by muse, mutect2, varscan2
- ABCA5 | c.3234del p.F1078Lfs*6 | Frame Shift Del (DEL) | VAF 209/743 reads (28%) | catalogued as COSV67016962; called by mutect2, pindel, varscan2
- ABCB11 | c.1613A>G p.Y538C | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750975007, COSV55602321; called by muse, mutect2, varscan2
- ABCC12 | c.2639C>T p.A880V | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60918610; called by muse, mutect2, varscan2
- ABL1 | c.3178G>A p.G1060S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); catalogued as rs777717678, COSV100583564, COSV59342288; called by muse, mutect2, varscan2
- ABLIM3 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV58638794; called by muse, mutect2, varscan2
- ABRAXAS1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 209/770 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200281698, COSV99788700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABTB1 | c.525A>G p.T175= (on ENST00000232744 / NM_172027.3; = p.T33= on NM_032548.3) | Splice Region (SNP) | VAF 65/254 reads (26%) | catalogued as COSV99230244; called by muse, mutect2
- ABTB2 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV54396391; called by muse, mutect2, varscan2
- AC004922.1 | c.1088A>G p.E363G | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV53165035, COSV99402817; called by muse, mutect2, varscan2
- AC011462.1 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as rs988176395, COSV54199980; called by muse, mutect2, varscan2
- ACACB | c.7246C>T p.R2416* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs771773850, COSV58147533; called by muse, mutect2, varscan2
- ACAP1 | c.1877T>G p.L626R | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV50142592; called by muse, mutect2
- ACP2 | c.301T>C p.Y101H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV57044142; called by muse, mutect2, varscan2
- ACRV1 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV59755480; called by muse, mutect2, varscan2
- ACTL6A | c.750G>A p.W250* | Nonsense Mutation (SNP) | VAF 70/214 reads (33%) | catalogued as COSV66999529; called by muse, mutect2, varscan2
- ACTN4 | c.2507C>T p.S836L | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs766882748, COSV53151095; called by muse, mutect2, varscan2
- ACTR3 | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 342/1142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54304433; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 104/178 reads (58%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM21 | c.2051del p.L684Cfs*3 | Frame Shift Del (DEL) | VAF 120/473 reads (25%) | catalogued as rs546931496; called by mutect2, pindel, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 60/166 reads (36%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS1 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs769915069, COSV53172815; called by muse, mutect2, varscan2
- ADAMTS10 | c.1511A>G p.K504R | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.304); catalogued as COSV54359880; called by muse, mutect2, varscan2
- ADAMTS16 | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs776256152, COSV57008326; called by muse, mutect2, varscan2
- ADAMTS18 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as rs1011453043, COSV51400271; called by muse, mutect2, varscan2
- ADAMTS20 | c.2998C>T p.R1000C | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as rs369101503; called by muse, mutect2, varscan2
- ADAMTS20 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101240713; called by muse, mutect2, varscan2
- ADAMTS4 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV63488823; called by muse, mutect2, varscan2
- ADCY3 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV99569261; called by muse, mutect2
- ADGRE5 | c.1021C>A p.L341M (on ENST00000242786 / NM_078481.4; = p.L248M on NM_001784.5) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV54415297; called by muse, mutect2, varscan2
- ADGRE5 | c.1331C>T p.A444V (on ENST00000242786 / NM_078481.4; = p.A351V on NM_001784.5) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV99663460; called by muse, mutect2, varscan2
- ADGRF4 | c.1906A>T p.I636F | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51958011, COSV99348464; called by muse, mutect2, varscan2
- ADGRL1 | c.667G>A p.V223I (on ENST00000340736 / NM_001008701.3; = p.V218I on NM_014921.5) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as rs754888851, COSV61566869; called by muse, mutect2, varscan2
- ADORA3 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as rs749922711, COSV53987076; called by muse, mutect2, varscan2
- AFF2 | c.1889A>G p.Q630R | Missense Mutation (SNP) | VAF 75/249 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV54009076; called by muse, mutect2, varscan2
- AGMAT | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199608628, COSV65436373; called by muse, mutect2, varscan2
- AGRN | c.3016del p.L1006Wfs*34 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | catalogued as COSV65070126; called by mutect2, pindel, varscan2
- AHDC1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.13); catalogued as rs776449449, COSV55937419, COSV99899852; called by muse, mutect2
- AKAP13 | c.8006G>A p.R2669H (on ENST00000394518 / NM_007200.5; = p.R2673H on NM_006738.6) | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs746154680, COSV63470943; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 187/601 reads (31%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP8L | c.1666_1668del p.E556del | In Frame Del (DEL) | VAF 18/67 reads (27%) | catalogued as rs775490570; called by pindel, varscan2
- AKAP9 | c.116dup p.R40Efs*7 | Frame Shift Ins (INS) | VAF 34/150 reads (23%) | catalogued as rs765201611; called by mutect2, varscan2
- ALAS2 | c.1432A>G p.I478V | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.268); catalogued as COSV58193540; called by muse, mutect2
- ALDH1A2 | c.1245G>T p.K415N | Missense Mutation (SNP) | VAF 85/247 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV51079092; called by muse, mutect2, varscan2
- ALDH1L1 | c.2377G>T p.D793Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV56419812; called by muse, mutect2, varscan2
- ALKBH5 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1315958769, COSV67687169; called by muse, mutect2, varscan2
- ANAPC2 | c.1485G>T p.K495N | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as COSV60572563; called by muse, mutect2, varscan2
- ANAPC5 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs115934510, COSV55841788; called by muse, mutect2, varscan2
- ANGPT2 | c.1159T>C p.Y387H | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57334698, COSV57340682; called by muse, mutect2, varscan2
- ANK3 | c.3628C>T p.R1210W (on ENST00000280772 / NM_001320874.2; = p.R344W on NM_001149.3) | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55084035; called by muse, mutect2, varscan2
- ANKRD10 | c.1243C>T p.H415Y | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV57445523; called by muse, mutect2, varscan2
- ANKRD11 | c.4667C>T p.A1556V | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs781186923, COSV56372947; called by muse, mutect2, varscan2
- ANKRD26 | c.3289G>T p.V1097L | Missense Mutation (SNP) | VAF 115/366 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as COSV65778698; called by muse, mutect2, varscan2
- ANKRD33 | c.223C>T p.R75W (on ENST00000340970 / NM_001304459.2; = p.R210W on NM_182608.4) | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs144402270; called by muse, mutect2, varscan2
- ANO5 | c.1747G>A p.V583I | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs375225649; called by muse, mutect2, varscan2
- ANO8 | c.2534C>T p.S845L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.726); catalogued as rs376028722; called by muse, mutect2, varscan2
- ANXA1 | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 116/342 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV57412879; called by muse, mutect2, varscan2
- AOC1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761385425, COSV62871033; called by muse, mutect2, varscan2
- AOPEP | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369261332; called by muse, mutect2, varscan2
- AP2A2 | c.2006del p.P669Lfs*67 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs770443312, COSV59961800; called by mutect2, varscan2
- AP5Z1 | c.2086del p.Q696Rfs*6 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as rs771683676, COSV100804281; called by mutect2, pindel, varscan2
- APBB3 | c.1321A>G p.M441V (on ENST00000357560 / NM_133173.2; = p.M448V on NM_006051.3) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760522044, COSV100296746; called by muse, mutect2
- API5 | c.571T>G p.F191V | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66635311; called by muse, mutect2, varscan2
- APOBEC1 | c.207del p.K69Nfs*12 | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | catalogued as rs753365818; called by mutect2, pindel, varscan2
- ARAP1 | c.3554C>T p.A1185V (on ENST00000393609 / NM_001040118.2; = p.A940V on NM_015242.4) | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100502312; called by muse, varscan2
- ARAP3 | c.2528del p.P843Qfs*72 | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | catalogued as rs1286143522; called by mutect2, pindel, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 57/245 reads (23%) | catalogued as rs773922861; called by mutect2, varscan2
- ARHGAP28 | c.1489C>T p.H497Y (on ENST00000383472 / NM_001366230.1; = p.H338Y on NM_001010000.3) | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV51646977; called by muse, mutect2, varscan2
- ARHGAP31 | c.2927C>T p.A976V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV51799695; called by muse, mutect2, varscan2
- ARHGAP9 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100712553; called by muse, mutect2, varscan2
- ARHGEF15 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV62726607; called by muse, mutect2, varscan2
- ARHGEF26 | c.1525A>C p.I509L | Missense Mutation (SNP) | VAF 128/407 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.924); catalogued as COSV62852433; called by muse, varscan2
- ARMC3 | c.152A>C p.K51T | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.697); catalogued as COSV53068301; called by muse, varscan2
- ARMC8 | c.352G>T p.D118Y (on ENST00000469044 / NM_001363941.2; = p.D104Y on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61769656; called by muse, mutect2, varscan2
- ASAH1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50504828; called by muse, varscan2
- ASCC3 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs760453996, COSV61227394, COSV61232687; called by muse, mutect2, varscan2
- ASIC3 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs150496362; called by muse, mutect2, varscan2
- ASIC4 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs776539734, COSV61731172; called by muse, mutect2, varscan2
- ASPM | c.3146G>A p.W1049* | Nonsense Mutation (SNP) | VAF 140/545 reads (26%) | catalogued as COSV54139587, COSV54141333; called by muse, varscan2
- ASPM | c.2993C>T p.P998L | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs971453990, COSV54129320; called by muse, mutect2, varscan2
- ASTE1 | c.481A>G p.S161G | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53910769; called by muse, mutect2, varscan2
- ASTN1 | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201600955, COSV56087176; called by muse, mutect2, varscan2
- ATIC | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 149/517 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs549649169, COSV52692704; called by muse, mutect2, varscan2
- ATP13A1 | c.2053G>A p.V685I | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs1310172840, COSV99366745; called by muse, varscan2
- ATP13A2 | c.3526G>A p.A1176T | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1250232618, COSV58704193; called by muse, mutect2, varscan2
- ATP13A2 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs113105667; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP13A3 | c.3079del p.W1027Gfs*31 | Frame Shift Del (DEL) | VAF 84/219 reads (38%) | catalogued as rs746602775; called by mutect2, varscan2
- ATP2A3 | c.1810C>T p.R604* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV59235597; called by muse, mutect2, varscan2
- ATP2C1 | c.234+2T>C p.X78_splice | Splice Site (SNP) | VAF 62/208 reads (30%) | catalogued as COSV60763203; called by muse, mutect2
- ATP5F1A | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.274); catalogued as rs201477144, COSV56362020; called by muse, mutect2, varscan2
- ATP8B2 | c.1280C>T p.T427M (on ENST00000672630; = p.T394M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1427625409, COSV59247791; called by muse, mutect2, varscan2
- ATPSCKMT | c.601del p.E201Rfs*3 | Frame Shift Del (DEL) | VAF 57/166 reads (34%) | catalogued as rs758128144; called by mutect2, pindel, varscan2
- AXDND1 | c.1306C>T p.H436Y | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV62649176; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as rs35951843; called by mutect2, pindel, varscan2
- B4GAT1 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV60820806; called by muse, mutect2, varscan2
- BACE1 | c.942C>T p.S314= | Splice Region (SNP) | VAF 69/246 reads (28%) | catalogued as rs748797299, COSV57286548; called by muse, mutect2, varscan2
- BAG6 | c.103del p.A35Pfs*3 | Frame Shift Del (DEL) | VAF 50/166 reads (30%) | catalogued as COSV52987953; called by mutect2, pindel, varscan2
- BARHL1 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.131); catalogued as rs966238637, COSV55038483; called by muse, mutect2, varscan2
- BCL2L15 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63643253, COSV63643408; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEND5 | c.1151C>G p.T384S | Missense Mutation (SNP) | VAF 209/659 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as COSV100884186; called by muse, mutect2, varscan2
- BFAR | c.1339A>G p.T447A | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99902523; called by muse, mutect2, varscan2
- BHMT2 | c.561A>G p.I187M | Missense Mutation (SNP) | VAF 85/307 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as COSV54874904; called by muse, mutect2, varscan2
- BIN3 | c.623A>G p.Y208C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1313958738, COSV52386708; called by muse, mutect2, varscan2
- BIRC6 | c.7588A>T p.T2530S | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.121); catalogued as COSV70206750; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3821A>G p.H1274R | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV63247560; called by muse, mutect2
- BLMH | c.313dup p.W105Lfs*5 | Frame Shift Ins (INS) | VAF 106/358 reads (30%) | catalogued as rs1567840429; called by mutect2, varscan2
- BMP1 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs756176995, COSV60476286; called by muse, mutect2, varscan2
- BPIFB2 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as rs199997957; called by muse, mutect2, varscan2
- BPIFB3 | c.371G>C p.G124A | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.584); catalogued as COSV64958252; called by muse, mutect2, varscan2
- BRCA1 | c.3724A>G p.T1242A | Missense Mutation (SNP) | VAF 58/319 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs80357037, COSV58800902; ClinVar: benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as rs763134487; called by mutect2, varscan2
- BRPF1 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57408365; called by muse, mutect2, varscan2
- BSCL2 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.092); catalogued as rs1266361176, COSV54017948; called by muse, mutect2, varscan2
- BSN | c.8728G>A p.A2910T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV56528514; called by muse, mutect2, varscan2
- BTAF1 | c.3071G>A p.R1024Q | Missense Mutation (SNP) | VAF 100/365 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758296724, COSV99795309; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 28/119 reads (24%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BUB3 | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767340055, COSV64364275; called by muse, mutect2, varscan2
- C14orf39 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 179/591 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV58785386; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 25/85 reads (29%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C1orf115 | c.302A>G p.Y101C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.976); catalogued as COSV54274610; called by muse, mutect2
- C2orf15 | c.173C>G p.T58R | Missense Mutation (SNP) | VAF 137/446 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV56782474; called by muse, mutect2, varscan2
- C2orf73 | c.498G>T p.Q166H | Missense Mutation (SNP) | VAF 107/382 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV58312190; called by muse, mutect2, varscan2
- C4orf17 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58513706; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- C9orf85 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs757324049, COSV58254648; called by muse, mutect2, varscan2
- CAB39L | c.285del p.D96Mfs*2 | Frame Shift Del (DEL) | VAF 59/207 reads (29%) | catalogued as COSV61714509; called by mutect2, pindel, varscan2
- CABCOCO1 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57596520; called by muse, mutect2, varscan2
- CABIN1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs777390432, COSV54084445; called by muse, mutect2, varscan2
- CABIN1 | c.5885C>T p.A1962V | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.006); catalogued as COSV99574240; called by muse, mutect2, varscan2
- CACNA1B | c.6143C>T p.S2048L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs751233267, COSV53150732; called by muse, mutect2, varscan2
- CACNA1C | c.6565C>T p.R2189C (on ENST00000399634 / NM_001167625.1; = p.R2118C on NM_000719.7) | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs769552189, COSV59703256; called by muse, mutect2, varscan2
- CACNA1D | c.3074T>G p.L1025R (on ENST00000350061 / NM_001128840.3; = p.L1045R on NM_000720.4) | Missense Mutation (SNP) | VAF 98/330 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99860535; called by muse, mutect2
- CACNA1E | c.3773G>A p.R1258Q | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62382257; called by muse, mutect2, varscan2
- CACNA1G | c.2545C>T p.P849S | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661892, COSV61740563; called by muse, mutect2, varscan2
- CACNA1H | c.1483G>A p.V495M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.06); catalogued as COSV100673715; called by muse, mutect2, varscan2
- CACNG3 | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.528); catalogued as rs147926451; called by muse, mutect2, varscan2
- CAD | c.6278T>C p.L2093P | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99256081; called by muse, mutect2
- CADM2 | c.881A>G p.Y294C (on ENST00000407528 / NM_001167674.2; = p.Y296C on NM_153184.4) | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67407068; called by muse, mutect2, varscan2
- CAMSAP1 | c.1161dup p.V388Rfs*19 | Frame Shift Ins (INS) | VAF 7/41 reads (17%) | catalogued as rs750552002; called by mutect2, pindel, varscan2
- CAPN6 | c.1853G>C p.G618A | Missense Mutation (SNP) | VAF 84/253 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as COSV60697444; called by muse, mutect2, varscan2
- CAPN9 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs1226218954, COSV55240242; called by muse, mutect2, varscan2
- CARF | c.2080A>G p.T694A | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV57550149; called by muse, mutect2, varscan2
- CASKIN2 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs374772637; called by muse, mutect2, varscan2
- CAV1 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 133/451 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100592068; called by muse, mutect2, varscan2
- CBFA2T3 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs760610315, COSV51925320; called by muse, mutect2, varscan2
- CCDC136 | c.2399A>G p.Y800C | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52805541; called by muse, mutect2, varscan2
- CCDC178 | c.1014G>T p.E338D | Missense Mutation (SNP) | VAF 104/413 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV55799313; called by muse, mutect2, varscan2
- CCDC180 | c.4614del p.K1539Nfs*17 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs1423532083; called by mutect2, pindel, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 176/522 reads (34%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 88/264 reads (33%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC54 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 133/463 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV53760002; called by muse, mutect2, varscan2
- CCDC62 | c.1043del p.N348Ifs*45 | Frame Shift Del (DEL) | VAF 60/224 reads (27%) | catalogued as rs1412762139; called by mutect2, varscan2
- CCDC82 | c.1141G>T p.D381Y | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53595659; called by muse, mutect2, varscan2
- CCDC87 | c.2410C>T p.P804S | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59580714; called by muse, mutect2, varscan2
- CCL22 | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99536679; called by muse, mutect2, varscan2
- CCL23 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 31/122 reads (25%) | catalogued as rs768484405; called by muse, mutect2, varscan2
- CCN2 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV63467062; called by muse, mutect2, varscan2
- CCNI2 | c.634T>C p.F212L | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66395158; called by muse, mutect2, varscan2
- CD22 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); catalogued as rs765142767, COSV50070614; called by muse, varscan2
- CD22 | c.2491G>A p.G831R | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as rs547905156, COSV50070684; called by muse, mutect2, varscan2
- CD320 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV56849084; called by muse, mutect2, varscan2
- CD33 | c.296A>T p.N99I | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.924); catalogued as COSV51805204, COSV99220891; called by muse, mutect2, varscan2
- CD46 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 362/1166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59735713; called by muse, mutect2, varscan2
- CD58 | c.254_255del p.T85Sfs*4 | Frame Shift Del (DEL) | VAF 147/504 reads (29%) | catalogued as COSV65665583; called by pindel, varscan2
- CDC37 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55770044; called by muse, mutect2, varscan2
- CDK12 | c.2791A>G p.T931A | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV71003057; called by muse, mutect2
- CDS1 | c.789del p.F263Lfs*6 | Frame Shift Del (DEL) | VAF 34/108 reads (31%) | catalogued as rs759091263; called by mutect2, varscan2
- CEACAM16 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754040589, COSV69188458, COSV69188693; called by muse, mutect2, varscan2
- CEL | c.832G>A p.A278T (on ENST00000673714; = p.A275T on NM_001807.6) | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV60829870; called by muse, mutect2, varscan2
- CELSR2 | c.2000T>C p.V667A | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV99605011; called by muse, mutect2, varscan2
- CENPJ | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 113/407 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV101121593; called by muse, mutect2, varscan2
- CEP97 | c.1855T>A p.F619I | Missense Mutation (SNP) | VAF 142/513 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1560022131, COSV59128381; called by muse, mutect2, varscan2
- CETP | c.795del p.T266Pfs*28 | Frame Shift Del (DEL) | VAF 37/128 reads (29%) | catalogued as rs1567472893; called by mutect2, pindel, varscan2
- CFAP43 | c.760C>A p.L254I | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as COSV53381719; called by muse, mutect2, varscan2
- CFHR5 | c.1667C>A p.A556E | Missense Mutation (SNP) | VAF 115/420 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as COSV56829370; called by muse, mutect2, varscan2
- CHAT | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1471251847, COSV60329821, COSV60333129; called by muse, mutect2, varscan2
- CHD1 | c.663_665dup p.D221dup | In Frame Ins (INS) | VAF 134/452 reads (30%) | catalogued as rs1054501824; called by mutect2, varscan2
- CHD2 | c.4910G>A p.R1637Q | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs752891322, COSV101245878; called by muse, mutect2, varscan2
- CHD6 | c.7097C>T p.A2366V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV64694882; called by muse, mutect2, varscan2
- CHD6 | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV58562789; called by muse, mutect2, varscan2
- CHD9 | c.5591T>C p.F1864S | Missense Mutation (SNP) | VAF 49/318 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54617141; called by muse, mutect2, varscan2
- CHD9 | c.5945C>T p.T1982I | Missense Mutation (SNP) | VAF 118/393 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54617153; called by muse, mutect2, varscan2
- CHD9 | c.6308G>A p.R2103H | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.707); catalogued as rs762580392, COSV54610216; called by muse, mutect2, varscan2
- CHRNA4 | c.812G>A p.C271Y | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64721254; called by muse, mutect2, varscan2
- CHUK | c.2053C>A p.P685T | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV64918821; called by muse, mutect2, varscan2
- CILP | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 44/112 reads (39%) | catalogued as rs150946463; called by muse, varscan2
- CIZ1 | c.1497A>G p.G499= | Splice Region (SNP) | VAF 31/134 reads (23%) | catalogued as COSV52974721; called by muse, mutect2, varscan2
- CLCA1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.867); catalogued as rs778883060, COSV52331721; called by muse, mutect2, varscan2
- CLIP3 | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.942); catalogued as COSV62113718; called by muse, mutect2, varscan2
- CMYA5 | c.11944C>T p.H3982Y | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV69746321; called by muse, mutect2, varscan2
- CNIH2 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 84/294 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as rs367930521; called by muse, mutect2, varscan2
- CNKSR2 | c.2416C>T p.R806W | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54267418; called by muse, mutect2, varscan2
- CNOT7 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63518469; called by muse, mutect2, varscan2
- CNTLN | c.4162dup p.I1388Nfs*3 | Frame Shift Ins (INS) | VAF 356/1472 reads (24%) | catalogued as rs1362524954; called by mutect2, pindel, varscan2
- CNTNAP1 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.272); catalogued as rs1298303462, COSV52854615; called by muse, mutect2, varscan2
- COA1 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs140065703; called by muse, mutect2, varscan2
- COL22A1 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs192060323, COSV57355025; called by muse, mutect2, varscan2
- COL27A1 | c.2296G>A p.G766S | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs752172699, COSV100621406; called by muse, mutect2, varscan2
- COL27A1 | c.3582T>A p.S1194R | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as COSV100621407; called by muse, mutect2, varscan2
- COL5A3 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 121/374 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs868272221, COSV53420063; called by muse, varscan2
- COL8A1 | c.2185G>A p.G729R | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs762335752, COSV53737456; called by muse, mutect2, varscan2
- COLEC12 | c.1112G>A p.C371Y | Missense Mutation (SNP) | VAF 229/736 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV68374231; called by muse, mutect2, varscan2
- COLQ | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.903); catalogued as rs201158622, COSV67524892, COSV67525091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPAMD8 | c.3153del p.H1052Ifs*127 (on ENST00000651564; = p.H1005Ifs*127 on NM_015692.5) | Frame Shift Del (DEL) | VAF 30/95 reads (32%) | catalogued as rs750161916, COSV71597321; called by mutect2, pindel, varscan2
- CPNE4 | c.1302G>A p.S434= | Splice Region (SNP) | VAF 52/163 reads (32%) | catalogued as rs1303493118, COSV70195920; called by muse, mutect2, varscan2
- CPT1A | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 150/448 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs1425369664, COSV99680741; called by muse, mutect2, varscan2
- CRCP | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV58536943; called by muse, mutect2, varscan2
- CSF1R | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV53838233; called by muse, mutect2, varscan2
- CSMD1 | c.5772C>G p.N1924K (on ENST00000520002; = p.N1923K on NM_033225.6) | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs773439188, COSV59389637; called by muse, mutect2, varscan2
- CSMD3 | c.9073C>T p.R3025C (on ENST00000297405 / NM_001363185.1; = p.R2856C on NM_052900.3) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775065918, COSV52095077; called by muse, mutect2, varscan2
- CSNK1G3 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as rs770657288, COSV62057158, COSV62057450; called by muse, mutect2, varscan2
- CSPG5 | c.1154G>A p.G385D | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53132947; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 60/201 reads (30%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- CTC1 | c.1754A>G p.Q585R | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as COSV100236919; called by muse, mutect2, varscan2
- CTNNA2 | c.2569T>C p.S857P | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.072); catalogued as COSV100562402; called by muse, mutect2, varscan2
- CTNNA3 | c.1594A>G p.N532D | Missense Mutation (SNP) | VAF 91/308 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.042); catalogued as rs1465548074, COSV65622650; called by muse, mutect2, varscan2
- CTSC | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as rs575727793, COSV57060631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTTNBP2 | c.1726G>T p.G576W | Missense Mutation (SNP) | VAF 164/523 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50484018; called by muse, mutect2, varscan2
- CUBN | c.3554A>G p.Y1185C | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64728146; called by muse, mutect2, varscan2
- CUL1 | c.2185C>T p.Q729* | Nonsense Mutation (SNP) | VAF 49/152 reads (32%) | catalogued as COSV57392857; called by muse, mutect2, varscan2
- CUL2 | c.1002C>T p.N334= | Splice Region (SNP) | VAF 70/205 reads (34%) | catalogued as rs746714817, COSV101039339; called by muse, mutect2, varscan2
- CUTC | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 97/303 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV65082285; called by muse, mutect2, varscan2
- CYBB | c.1360T>C p.F454L | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV66086449; called by muse, mutect2, varscan2
- CYFIP2 | c.2674G>A p.A892T (on ENST00000616178 / NM_001291722.2; = p.A867T on NM_014376.4) | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.135); catalogued as COSV56638271; called by muse, mutect2, varscan2
- DAZAP2 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs758764846, COSV66313300; called by muse, mutect2, varscan2
- DBF4B | c.1412A>G p.E471G | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); catalogued as COSV59264083; called by muse, mutect2, varscan2
- DCAF12L2 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.162); catalogued as COSV100758937; called by muse, mutect2, varscan2
- DCC | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs112433088, COSV59087894; called by muse, mutect2, varscan2
- DCTN1 | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.88); catalogued as COSV62621605; called by muse, mutect2, varscan2
- DDX19A | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 139/412 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100156551; called by muse, varscan2
- DDX43 | c.1092del p.G365Vfs*2 | Frame Shift Del (DEL) | VAF 128/486 reads (26%) | catalogued as rs1424884917, COSV64836411; called by mutect2, pindel, varscan2
- DDX51 | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57960295; called by muse, mutect2, varscan2
- DELE1 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52006763; called by muse, mutect2, varscan2
- DENND1A | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65333183; called by muse, varscan2
- DENND1C | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV67375460; called by muse, mutect2, varscan2
- DENND2A | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.609); catalogued as COSV52059799; called by muse, mutect2, varscan2
- DGKH | c.1366A>G p.R456G | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99819820; called by muse, mutect2
- DGKK | c.1898A>G p.Q633R | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.549); catalogued as COSV101053277; called by muse, mutect2, varscan2
- DHPS | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52953444; called by muse, mutect2, varscan2
- DHRS4L2 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100632688; called by muse, mutect2, varscan2
- DHX30 | c.2638G>A p.D880N (on ENST00000445061 / NM_138615.3; = p.D841N on NM_014966.3) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as COSV53143215; called by muse, mutect2, varscan2
- DHX40 | c.1901G>A p.R634K | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.807); catalogued as COSV52069149; called by muse, mutect2, varscan2
- DHX57 | c.2195del p.L732Wfs*7 | Frame Shift Del (DEL) | VAF 64/184 reads (35%) | catalogued as rs749610132; called by mutect2, varscan2
- DIAPH2 | c.1391A>T p.D464V | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100236110; called by muse, mutect2, varscan2
- DIPK1A | c.401T>C p.I134T | Missense Mutation (SNP) | VAF 47/310 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs375926241; called by muse, mutect2, varscan2
- DISC1 | c.2202del p.R735Gfs*12 | Frame Shift Del (DEL) | VAF 41/147 reads (28%) | catalogued as COSV100790088; called by mutect2, pindel, varscan2
- DISP3 | c.3805del p.H1269Tfs*66 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as rs756156984; called by mutect2, pindel, varscan2
- DLG5 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488016884, COSV64948531; called by muse, mutect2, varscan2
- DLGAP4 | c.2449C>T p.R817W (on ENST00000339266 / NM_001365621.1; = p.R814W on NM_014902.6) | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV59418677; called by muse, mutect2
- DMAP1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.147); catalogued as rs1435165317, COSV59999858; called by muse, mutect2, varscan2
- DMBX1 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63602655; called by muse, mutect2, varscan2
- DMPK | c.482G>T p.S161I | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52182647; called by muse, varscan2
- DMTN | c.281dup p.P95Tfs*38 | Frame Shift Ins (INS) | VAF 32/126 reads (25%) | catalogued as rs772208110; called by mutect2, varscan2
- DNAH11 | c.8918C>T p.A2973V | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV60984129; called by muse, mutect2, varscan2
- DNAH11 | c.9275T>C p.V3092A | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV60984138; called by muse, mutect2, varscan2
- DNAH17 | c.10804C>T p.R3602C | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs568734889, COSV67761754; called by muse, mutect2, varscan2
- DNAH17 | c.5082G>T p.Q1694H | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67761759; called by muse, mutect2, varscan2
- DNAH17 | c.2741C>T p.P914L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs370734377, COSV101101682, COSV67761060; called by muse, mutect2, varscan2
- DNAH3 | c.7894G>A p.V2632I | Missense Mutation (SNP) | VAF 91/299 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); catalogued as rs149187610; called by muse, mutect2, varscan2
- DNAH7 | c.5035G>A p.A1679T | Missense Mutation (SNP) | VAF 98/352 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV56788647; called by muse, mutect2, varscan2
- DNAI3 | c.1538C>T p.T513I | Missense Mutation (SNP) | VAF 109/366 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54006573; called by muse, mutect2, varscan2
- DNAJC10 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51147507; called by muse, mutect2, varscan2
- DNAJC9 | c.433A>G p.M145V | Missense Mutation (SNP) | VAF 112/370 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.391); catalogued as COSV54355035; called by muse, mutect2
- DNER | c.1247G>A p.C416Y | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59160544, COSV59177503; called by muse, mutect2, varscan2
- DNM3 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62467985; called by muse, mutect2, varscan2
- DNMBP | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs373777411; called by muse, mutect2, varscan2
- DOC2A | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV58752963; called by muse, mutect2, varscan2
- DOCK2 | c.808A>T p.I270F | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as COSV99916286; called by muse, mutect2, varscan2
- DOCK2 | c.5218G>A p.A1740T | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs535531464, COSV56990353; called by muse, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 71/216 reads (33%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.5630C>T p.P1877L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.019); catalogued as rs766058170, COSV70239454; called by muse, varscan2
- DOCK4 | c.2879G>A p.R960H | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs751945004, COSV70236375; called by muse, mutect2, varscan2
- DPPA2 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.778); catalogued as rs199811743; called by muse, mutect2, varscan2
- DSCAM | c.3536A>G p.Q1179R | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.728); catalogued as COSV68037184; called by muse, mutect2
- DSPP | c.2330G>A p.S777N | Missense Mutation (SNP) | VAF 104/338 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.071); catalogued as COSV99218231; called by muse, mutect2, varscan2
- DST | c.17365G>A p.A5789T (on ENST00000361203 / NM_001374722.1; = p.A3486T on NM_015548.5) | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs375644963; called by muse, mutect2, varscan2
- DUS1L | c.132C>A p.C44* | Nonsense Mutation (SNP) | VAF 25/86 reads (29%) | catalogued as COSV60785617; called by muse, mutect2, varscan2
- ECM2 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs776249213, COSV100755800, COSV60743103; called by muse, mutect2, varscan2
- EDC4 | c.2401del p.D801Mfs*15 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as COSV100197699; called by mutect2, pindel, varscan2
- EEF2K | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53779802; called by muse, mutect2, varscan2
- EEF2K | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1233232544, COSV53778147; called by muse, mutect2, varscan2
- EFCAB13 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 122/414 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV58953127; called by muse, mutect2
- EFEMP1 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 33/134 reads (25%) | catalogued as rs1307987501, COSV62616481; called by muse, mutect2, varscan2
- EHBP1 | c.3146C>T p.A1049V | Missense Mutation (SNP) | VAF 78/327 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1200456239, COSV99859694; called by muse, mutect2, varscan2
- ELANE | c.67+1del | Frame Shift Del (DEL) | VAF 19/75 reads (25%) | catalogued as rs886039350; ClinVar: uncertain significance; called by mutect2, varscan2
- ELF4 | c.1021del p.Q341Rfs*30 | Frame Shift Del (DEL) | VAF 23/79 reads (29%) | catalogued as COSV57452819, COSV57454138; called by mutect2, pindel, varscan2
- ELOVL7 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV70918754; called by muse, mutect2, varscan2
- EML3 | c.212dup p.L72Tfs*46 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs765689252; called by mutect2, varscan2
- ENGASE | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56137959; called by muse, mutect2, varscan2
- ENTPD7 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 97/290 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.86); catalogued as rs759793937, COSV65113344; called by muse, mutect2, varscan2
- EP300 | c.4717A>G p.M1573V | Missense Mutation (SNP) | VAF 98/340 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs759652679, COSV54346283; called by muse, varscan2
- EP400 | c.3872G>A p.R1291H | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs761082851, COSV57764103; called by muse, mutect2, varscan2
- EPC2 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); catalogued as COSV51550014; called by muse, mutect2, varscan2
- EPG5 | c.6308A>G p.D2103G | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.719); catalogued as COSV56356566; called by muse, mutect2, varscan2
- EPHB2 | c.2680G>A p.A894T (on ENST00000400191 / NM_001309193.2; = p.A895T on NM_004442.7) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV65867107; called by muse, mutect2, varscan2
- EPHB4 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.051); catalogued as COSV62270708; called by muse, mutect2, varscan2
- EPS8L1 | c.809G>T p.S270I (on ENST00000201647 / NM_133180.3; = p.S143I on NM_017729.3) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV52386663; called by muse, mutect2, varscan2
- ERAP2 | c.2865G>A p.W955* | Nonsense Mutation (SNP) | VAF 62/311 reads (20%) | catalogued as COSV65941511; called by muse, mutect2, varscan2
- ERP44 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 210/694 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1450917325, COSV52435470; called by muse, mutect2, varscan2
- ESPNL | c.1448C>A p.A483E | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as rs570258039, COSV100547994, COSV58034956; called by mutect2, varscan2
- ETV6 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV67154561; called by muse, mutect2, varscan2
- EXOC5 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs775385616, COSV61772472; called by muse, mutect2, varscan2
- EXT1 | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 120/484 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as COSV65475092; called by muse, mutect2, varscan2
- EYA4 | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV62061506; called by muse, mutect2, varscan2
- F8 | c.5338C>T p.P1780S | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM062664, CM1314173, COSV64279166; called by muse, mutect2, varscan2
- FADS3 | c.605T>C p.F202S | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV53880703; called by muse, mutect2, varscan2
- FAHD2A | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 178/598 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51979312; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 51/174 reads (29%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM120B | c.1588C>G p.Q530E | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.036); catalogued as COSV53008534, COSV53008789; called by muse, mutect2, varscan2
- FAM120B | c.2596G>A p.A866T | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs900275467, COSV53008798; called by muse, mutect2, varscan2
- FAM135A | c.1034G>A p.R345H (on ENST00000370479 / NM_001351599.1; = p.R328H on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371440122; called by muse, mutect2, varscan2
- FAM214A | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as rs969658360, COSV55927469; called by muse, mutect2, varscan2
- FAM90A1 | c.137del p.N46Tfs*16 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as COSV56712291; called by mutect2, pindel
- FAM98A | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.903); catalogued as COSV53212104; called by muse, mutect2, varscan2
- FAP | c.1804A>G p.T602A | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV51868084; called by muse, mutect2, varscan2
- FAT2 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs758396931, COSV55830318; called by muse, mutect2, varscan2
- FAT3 | c.11408C>T p.P3803L | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as rs369650040, COSV53071949; called by muse, mutect2, varscan2
- FAT4 | c.4228G>A p.V1410M | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781736766, COSV101272852, COSV67881199, COSV67899529; called by muse, mutect2, varscan2
- FBXO31 | c.412+1G>A p.X138_splice | Splice Site (SNP) | VAF 38/118 reads (32%) | catalogued as rs1251302168, COSV61151601; called by muse, mutect2, varscan2
- FBXO5 | c.615A>T p.L205F | Missense Mutation (SNP) | VAF 121/383 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779584167, COSV57671556, COSV57671698; called by mutect2, varscan2
- FCGBP | c.8503G>A p.G2835R | Missense Mutation (SNP) | VAF 144/487 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs747177556; called by muse, mutect2, varscan2
- FCGRT | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.464); catalogued as rs144900355; called by muse, mutect2, varscan2
- FCMR | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 141/422 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs995859431, COSV65569691; called by muse, mutect2, varscan2
- FER1L5 | c.4654A>G p.M1552V (on ENST00000623019; = p.M1525V on NM_001293083.2) | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV67607169; called by muse, mutect2
- FGD1 | c.1511G>A p.C504Y | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64309747; called by muse, mutect2, varscan2
- FGF18 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as rs775534638, COSV51129798; called by muse, mutect2, varscan2
- FGF20 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV99471693; called by muse, varscan2
- FHDC1 | c.2617G>A p.G873R | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.579); catalogued as rs757283743, COSV52602425; called by muse, mutect2, varscan2
- FHOD3 | c.2161C>T p.Q721* (on ENST00000359247 / NM_001281739.3; = p.Q738* on NM_025135.5) | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as COSV57189751; called by muse, mutect2, varscan2
- FILIP1 | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 81/263 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs755925479, COSV52727083; called by muse, mutect2, varscan2
- FLNA | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs924631524, COSV61038176; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNB | c.3734G>A p.R1245Q | Missense Mutation (SNP) | VAF 99/278 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs776611311, COSV55897108; called by muse, mutect2, varscan2
- FLNC | c.4275del p.R1426Gfs*12 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | catalogued as COSV57955877, COSV57964626; called by mutect2, pindel
- FMN2 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1432513429, COSV60456096; called by muse, mutect2, varscan2
- FMN2 | c.4405C>A p.R1469S | Missense Mutation (SNP) | VAF 178/561 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.597); catalogued as COSV60456107; called by muse, mutect2, varscan2
- FMNL2 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs755508231, COSV56505422; called by muse, mutect2, varscan2
- FMNL3 | c.2930G>A p.R977H | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs369272662; called by muse, mutect2, varscan2
- FMO1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.744); catalogued as COSV61445651; called by muse, mutect2, varscan2
- FMO5 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV54211027; called by muse, mutect2, varscan2
- FNBP1L | c.1381C>A p.L461I (on ENST00000271234 / NM_001164473.2; = p.L403I on NM_017737.5) | Missense Mutation (SNP) | VAF 114/369 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53096888; called by muse, mutect2, varscan2
- FNDC4 | c.30del p.S11Afs*17 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs771665646, COSV99253963; called by mutect2, varscan2
- FNIP1 | c.2777C>T p.A926V | Missense Mutation (SNP) | VAF 92/339 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.173); catalogued as COSV57201065; called by mutect2, varscan2
- FOXK2 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as rs1452153422, COSV100082523; called by muse, mutect2, varscan2
- FOXN1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs774400145, COSV56884495, COSV99881615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRK | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 61/247 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73383832; called by muse, mutect2
- FRMPD3 | c.3039del p.S1014Afs*18 | Frame Shift Del (DEL) | VAF 34/121 reads (28%) | catalogued as rs752351689; called by mutect2, pindel, varscan2
- FUBP1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 193/713 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.232); catalogued as COSV53939385; called by muse, mutect2, varscan2
- FUT1 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs771713990, COSV59570215; called by muse, mutect2, varscan2
- GABBR1 | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 58/353 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.499); catalogued as rs1243700899, COSV63542877; called by muse, mutect2, varscan2
- GABRE | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as rs773238598, COSV64819424; called by muse, mutect2, varscan2
- GAL3ST3 | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.802); catalogued as COSV100361031; called by muse, mutect2
- GAL3ST3 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs769780407, COSV100361046; called by muse, varscan2
- GAMT | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.144); catalogued as COSV52041457; called by muse, mutect2, varscan2
- GAS2L1 | c.1839del p.P614Hfs*2 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs78929040; called by mutect2, varscan2
- GBF1 | c.5155A>G p.K1719E (on ENST00000369983 / NM_001377137.1; = p.K1718E on NM_004193.3) | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100890738; called by muse, mutect2
- GBP1 | c.1160A>G p.Q387R | Missense Mutation (SNP) | VAF 163/658 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as COSV65084601; called by muse, mutect2, varscan2
- GCA | c.262+1G>A p.X88_splice | Splice Site (SNP) | VAF 90/331 reads (27%) | catalogued as rs200701176, COSV52026941, COSV52027240; called by muse, mutect2, varscan2
- GDF7 | c.393C>T p.D131= | Splice Region (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99694255; called by muse, mutect2
- GEM | c.174G>A p.W58* | Nonsense Mutation (SNP) | VAF 59/158 reads (37%) | catalogued as COSV52599384; called by muse, mutect2, varscan2
- GEMIN8 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs749314407, COSV60550720; called by muse, mutect2, varscan2
- GGT5 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1026801373, COSV54068813; called by muse, mutect2, varscan2
- GGT7 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs372362464; called by muse, mutect2, varscan2
- GJA10 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs142743523, COSV65355701; called by muse, mutect2, varscan2
- GJA5 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); catalogued as rs121434557, CM068637, COSV54786869, COSV99053976; called by muse, mutect2, varscan2
- GK2 | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 158/529 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV62628550; called by muse, mutect2, varscan2
- GLI1 | c.2119C>A p.P707T | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.522); catalogued as COSV99954846; called by muse, mutect2, varscan2
- GLI3 | c.3163G>A p.G1055S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs1343190471, COSV67895389; called by muse, mutect2, varscan2
- GLI3 | c.2765C>T p.T922M | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773038952, COSV67895392; called by muse, mutect2, varscan2
- GLS2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 82/255 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs750601118, COSV61738510; called by muse, mutect2, varscan2
- GLUD2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV60153330; called by muse, mutect2, varscan2
- GLYR1 | c.932C>G p.A311G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58927348; called by muse, mutect2, varscan2
- GMIP | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1354863629, COSV99179391; called by muse, mutect2, varscan2
- GNPAT | c.1760T>C p.L587P | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64154438; called by muse, mutect2, varscan2
- GP2 | c.1276C>T p.R426C (on ENST00000381362 / NM_001007240.3; = p.R423C on NM_001502.4) | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.892); catalogued as rs201001285, COSV56891908; called by muse, mutect2, varscan2
- GPATCH8 | c.4292C>T p.A1431V | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1275669766, COSV59198867; called by muse, mutect2, varscan2
- GPC3 | c.1280A>G p.E427G | Missense Mutation (SNP) | VAF 185/580 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV100893697; called by muse, mutect2, varscan2
- GPC5 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV65587763; called by muse, mutect2, varscan2
- GPER1 | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99867511; called by muse, mutect2, varscan2
- GPER1 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs569932251, COSV52470849; called by mutect2, varscan2
- GPR137 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057129800, COSV57402308; called by muse, mutect2, varscan2
- GPR139 | c.57del p.G20Afs*27 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV58504119; called by mutect2, pindel
- GPR146 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as rs754291447, COSV52467228; called by muse, mutect2, varscan2
- GPR84 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 84/262 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs137983696; called by muse, mutect2, varscan2
- GRIK2 | c.1017G>T p.Q339H | Missense Mutation (SNP) | VAF 103/397 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV59775860; called by muse, mutect2, varscan2
- GRIN2A | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58045976; called by muse, mutect2, varscan2
- GRIP2 | c.1345C>A p.L449M (on ENST00000619221; = p.L352M on NM_001080423.4) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.642); catalogued as COSV56119606, COSV99817826; called by muse, mutect2, varscan2
- GRXCR1 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 104/316 reads (33%) | catalogued as COSV67674999; called by muse, mutect2, varscan2
- GTF2H1 | c.1387C>T p.H463Y | Missense Mutation (SNP) | VAF 102/351 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV99786703; called by muse, varscan2
- GTF3C1 | c.2518G>T p.G840C | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV62238929; called by muse, mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 172/602 reads (29%) | catalogued as rs1231771183; called by mutect2, varscan2
- GXYLT2 | c.932G>A p.W311* | Nonsense Mutation (SNP) | VAF 93/296 reads (31%) | catalogued as COSV67475309; called by muse, mutect2, varscan2
- GYG2 | c.682T>C p.Y228H | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58551945; called by muse, mutect2, varscan2
- H2AX | c.248A>G p.H83R | Missense Mutation (SNP) | VAF 85/271 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV99598263; called by muse, mutect2, varscan2
- H3C2 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV52520108; called by muse, mutect2, varscan2
- H3C7 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.262); catalogued as COSV55099684; called by muse, mutect2, varscan2
- HAP1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57879043; called by muse, mutect2, varscan2
- HAUS6 | c.1588del p.S530Vfs*12 | Frame Shift Del (DEL) | VAF 129/495 reads (26%) | catalogued as rs34558496; called by mutect2, pindel, varscan2
- HCFC1 | c.2723C>T p.T908M | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60078158; called by muse, mutect2, varscan2
- HCFC1 | c.1367del p.P456Rfs*34 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as COSV60078370; called by mutect2, pindel
- HCK | c.637del p.R213Efs*77 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as rs1568993585, COSV52940118; called by mutect2, pindel, varscan2
- HDGF | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 127/391 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV61978087; called by muse, mutect2, varscan2
- HDGFL2 | c.246G>T p.W82C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56684080; called by muse, mutect2, varscan2
- HEATR5A | c.1897_1899del p.L633del | In Frame Del (DEL) | VAF 31/128 reads (24%) | catalogued as rs778450871; called by pindel, varscan2
- HECTD1 | c.3658A>G p.K1220E | Missense Mutation (SNP) | VAF 166/594 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV67948240; called by muse, mutect2, varscan2
- HECW2 | c.3049del p.R1017Gfs*19 | Frame Shift Del (DEL) | VAF 85/295 reads (29%) | catalogued as COSV53659589; called by mutect2, pindel, varscan2
- HEPH | c.2215G>A p.A739T (on ENST00000343002; = p.A472T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57973147; called by muse, mutect2, varscan2
- HEPHL1 | c.1693G>T p.V565F | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV59896917; called by muse, mutect2, varscan2
- HERC2 | c.1991G>A p.C664Y | Missense Mutation (SNP) | VAF 96/303 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55352207; called by muse, mutect2, varscan2
- HHIP | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754135826, COSV56837387; called by muse, mutect2, varscan2
- HHIP | c.1085A>G p.D362G | Missense Mutation (SNP) | VAF 93/288 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV56844584; called by muse, mutect2, varscan2
- HIC1 | c.313C>T p.R105C (on ENST00000322941 / NM_001098202.1; = p.R86C on NM_006497.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759366814, COSV53977048; called by muse, mutect2
- HIF1A | c.173C>A p.S58Y | Missense Mutation (SNP) | VAF 103/323 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60191960; called by muse, mutect2, varscan2
- HIF1A | c.917G>T p.R306M | Missense Mutation (SNP) | VAF 112/324 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60191981; called by muse, varscan2
- HIP1R | c.3073C>T p.R1025W | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs149673932; called by muse, mutect2, varscan2
- HIVEP1 | c.791T>A p.V264D | Missense Mutation (SNP) | VAF 73/294 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV65105349; called by muse, mutect2, varscan2
- HK3 | c.2272dup p.E758Gfs*38 | Frame Shift Ins (INS) | VAF 27/89 reads (30%) | catalogued as rs35180023; called by mutect2, pindel, varscan2
- HLA-C | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66119418; called by muse, mutect2
- HLA-DMA | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as rs768509769, COSV66386201; called by muse, mutect2, varscan2
- HNRNPL | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV55495637; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs767148651; called by mutect2, varscan2
- HOXD4 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs542100496, COSV60460556; called by muse, mutect2
- HPS1 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57268854; called by muse, mutect2, varscan2
- HRH4 | c.920T>A p.I307N | Missense Mutation (SNP) | VAF 229/809 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99908071; called by muse, mutect2, varscan2
- HROB | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1364967465, COSV55369975; called by muse, mutect2, varscan2
- HTATSF1 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV99511984; called by muse, mutect2, varscan2
- HTR1B | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1010352208, COSV64051996; called by muse, mutect2, varscan2
- HTRA3 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs137866031; called by muse, mutect2, varscan2
- HYAL3 | c.985-2A>G p.X329_splice | Splice Site (SNP) | VAF 25/72 reads (35%) | catalogued as COSV60187364; called by muse, mutect2
- HYAL4 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs1481760488, COSV56140538; called by muse, mutect2, varscan2
- HYOU1 | c.2332G>A p.A778T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs782654390, COSV68217234; called by muse, mutect2, varscan2
- IFNAR1 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 103/411 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as rs541858922, COSV54254606; called by muse, mutect2, varscan2
- IFT172 | c.2834T>C p.I945T | Missense Mutation (SNP) | VAF 73/238 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV53140080; called by muse, mutect2, varscan2
- IGFALS | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs779943562, COSV51908716; called by muse, mutect2, varscan2
- IGFBP3 | c.752G>A p.C251Y | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51873605; called by muse, mutect2, varscan2
- IGSF1 | c.3185G>A p.G1062D | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV63837543; called by muse, mutect2, varscan2
- IGSF11 | c.703C>A p.P235T (on ENST00000393775 / NM_001015887.3; = p.P234T on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV61172405, COSV61179243; called by muse, mutect2
- IHO1 | c.1504C>A p.L502M | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV56511378; called by muse, mutect2, varscan2
- IL12RB2 | c.1655G>A p.C552Y | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52027635; called by muse, mutect2, varscan2
- IL1B | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 109/336 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs766684369, COSV54521258; called by muse, mutect2, varscan2
- IL20 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 125/407 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV65585204; called by muse, mutect2, varscan2
- IL2RG | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs970059158, COSV52150313; called by muse, mutect2, varscan2
- ILVBL | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs141415835, COSV54623126; called by muse, mutect2, varscan2
- INPPL1 | c.1747C>T p.L583F | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53359661; called by muse, mutect2, varscan2
- INSIG1 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 87/303 reads (29%) | catalogued as rs1383243939, COSV60921057; called by muse, mutect2, varscan2
- INSYN2A | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54748566, COSV54750854; called by muse, mutect2
- INTS4 | c.2410C>T p.R804* | Nonsense Mutation (SNP) | VAF 108/352 reads (31%) | catalogued as rs1270773866, COSV100490197; called by muse, mutect2, varscan2
- IRS4 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.2); catalogued as COSV64536138; called by muse, mutect2, varscan2
- ISLR2 | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs781082368, COSV62303896; called by muse, mutect2, varscan2
- ITGA1 | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50900621; called by muse, mutect2, varscan2
- ITGA11 | c.3451G>T p.G1151W | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59882354; called by muse, mutect2, varscan2
- ITGA4 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 106/413 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs1354333812, COSV67899184; called by muse, mutect2, varscan2
- ITGA9 | c.557A>C p.K186T | Missense Mutation (SNP) | VAF 204/627 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV53253743; called by muse, mutect2
- ITGAX | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs754976444, COSV51652118; called by muse, mutect2, varscan2
- ITGB1 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 119/457 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56487147; called by muse, mutect2, varscan2
- ITIH4 | c.1430T>C p.V477A | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV99820056; called by muse, mutect2, varscan2
- ITPK1 | c.848T>C p.I283T | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99969143; called by muse, mutect2, varscan2
- JAKMIP2 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs371879474; called by muse, mutect2, varscan2
- JAML | c.680C>T p.S227L (on ENST00000356289 / NM_001098526.2; = p.S217L on NM_153206.3) | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV52629789; called by muse, mutect2, varscan2
- JMJD6 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as COSV100373409; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as rs1424463115, COSV58028545; called by muse, mutect2, varscan2
- JPH3 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567595736, COSV52465027; called by muse, mutect2, varscan2
- JUP | c.1652C>T p.T551M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.489); catalogued as rs1038719021, COSV60279499; called by muse, mutect2, varscan2
- KANK1 | c.3616G>A p.A1206T | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779819624, COSV66527976; called by muse, mutect2, varscan2
- KASH5 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.855); catalogued as rs777228692, COSV71358237, COSV71358598; called by muse, mutect2, varscan2
- KAT2B | c.1907A>T p.Y636F | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.519); catalogued as COSV55435002; called by muse, mutect2, varscan2
- KBTBD4 | c.1156del p.E386Rfs*27 | Frame Shift Del (DEL) | VAF 88/255 reads (35%) | catalogued as rs756343868; called by mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | catalogued as rs754892524; called by mutect2, varscan2
- KCNA6 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV54978235; called by muse, mutect2, varscan2
- KCNB2 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.321); catalogued as rs760922089, COSV73053176; called by muse, mutect2, varscan2
- KCNE5 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV64508671; called by muse, mutect2, varscan2
- KCNH2 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs199472901, CM993712, COSV100060568; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- KCNH7 | c.2719A>G p.T907A | Missense Mutation (SNP) | VAF 127/428 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs765100442, COSV59814981; called by muse, mutect2, varscan2
- KCNJ4 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as COSV57858937; called by muse, mutect2, varscan2
- KCNJ9 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63632499; called by muse, mutect2, varscan2
- KCNK2 | c.41C>A p.A14E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as COSV67210832; called by muse, varscan2
- KCNN2 | c.1264G>A p.A422T (on ENST00000264773; = p.A634T on NM_021614.4) | Missense Mutation (SNP) | VAF 155/460 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV53299958; called by muse, mutect2, varscan2
- KCNQ5 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1390470611, COSV59684254; called by muse, mutect2, varscan2
- KCNS2 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54641275; called by muse, mutect2, varscan2
- KIAA1109 | c.1712A>G p.D571G | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs748693020, COSV52694723; called by muse, varscan2
- KIAA2013 | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 81/292 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1307721202, COSV64860904, COSV64861228; called by muse, mutect2, varscan2
- KIF24 | c.1298A>G p.Q433R | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757062155, COSV100799448; called by muse, mutect2
- KIFC3 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs183425954, COSV65549139, COSV65553364; called by muse, mutect2, varscan2
- KLHDC3 | c.401del p.C134Lfs*3 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | catalogued as COSV55065825; called by mutect2, pindel, varscan2
- KLHL3 | c.1477T>C p.Y493H | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV59058048; called by muse, mutect2, varscan2
- KLHL30 | c.1717G>A p.G573S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs747062547, COSV59976001, COSV59978799; called by muse, mutect2, varscan2
- KLHL31 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 122/409 reads (30%) | catalogued as rs182861065, COSV63882493; called by muse, mutect2, varscan2
- KLK8 | c.59del p.G20Efs*44 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs756039646; called by mutect2, pindel, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as COSV55868319; called by mutect2, pindel, varscan2
- KRT10 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 92/503 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as COSV54090689; called by muse, mutect2, varscan2
- KRT28 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs768445733, COSV60686608; called by muse, mutect2, varscan2
- KRT33A | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as rs1386858369, COSV50376873; called by muse, mutect2, varscan2
- LAMA1 | c.7714C>T p.H2572Y | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs1179436742, COSV67544921; called by muse, mutect2, varscan2
- LAX1 | c.1011G>T p.R337S | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV65850233; called by muse, mutect2, varscan2
- LCN10 | c.32T>C p.V11A | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1244874830, COSV57911789; called by muse, mutect2, varscan2
- LDHAL6A | c.53T>C p.I18T | Missense Mutation (SNP) | VAF 74/281 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV55009593; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LGR5 | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV57004005; called by muse, mutect2, varscan2
- LHPP | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 74/236 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs142666958; called by muse, mutect2, varscan2
- LHX2 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs755961022, COSV65319202; called by muse, mutect2, varscan2
- LINGO1 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.109); catalogued as COSV62438719; called by muse, mutect2, varscan2
- LMBRD1 | c.866G>A p.R289H (on ENST00000649011; = p.R267H on NM_018368.4) | Missense Mutation (SNP) | VAF 117/399 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs140874824; called by muse, mutect2, varscan2
- LMF1 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV51902868; called by muse, mutect2, varscan2
- LPO | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV51862940; called by muse, varscan2
- LRFN4 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV58923066; called by muse, mutect2, varscan2
- LRP1 | c.5974G>A p.A1992T | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769741036, COSV54519007; called by muse, mutect2, varscan2
- LRP1B | c.9103T>C p.Y3035H | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV67278938; called by muse, mutect2, varscan2
- LRP2 | c.10493G>A p.R3498H | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs534940314, COSV55562409; called by muse, mutect2, varscan2
- LRR1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 85/304 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777495090, COSV53562554; called by muse, mutect2, varscan2
- LRRC27 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs533190111, COSV59808535; called by muse, mutect2, varscan2
- LRRC29 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100441042; called by muse, mutect2, varscan2
- LRRC37A2 | c.3583G>A p.A1195T | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV61004514; called by muse, mutect2, varscan2
- LRRC57 | c.679T>C p.Y227H | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53001353; called by muse, mutect2, varscan2
- LRRIQ1 | c.4624del p.I1542Ffs*17 | Frame Shift Del (DEL) | VAF 46/171 reads (27%) | catalogued as rs745692987; called by mutect2, varscan2
- LRRN1 | c.1411A>G p.T471A | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV60016499; called by muse, mutect2, varscan2
- LRRTM1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54447186, COSV99702237; called by muse, mutect2, varscan2
- LTBP2 | c.4229G>A p.R1410H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs543585255, COSV56214674; called by muse, mutect2, varscan2
- LTBP4 | c.3850G>A p.G1284S (on ENST00000308370 / NM_001042544.1; = p.G1247S on NM_003573.2) | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as rs761032774, COSV52578107; called by muse, varscan2
- LYNX1 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs756554170, COSV59990238; called by muse, mutect2, varscan2
- LYVE1 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 290/972 reads (30%) | catalogued as rs775409214, COSV56283682; called by muse, mutect2, varscan2
- LZTR1 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781776791, COSV53145080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LZTS3 | c.1936G>A p.A646T (on ENST00000329152; = p.A600T on NM_001282533.2) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV53910067; called by muse, mutect2, varscan2
- MACROD2 | c.1080T>A p.N360K (on ENST00000642719; = p.N332K on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/373 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV54060567; called by muse, mutect2, varscan2
- MADD | c.2903G>A p.R968Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767356267, COSV60630048; called by muse, mutect2, varscan2
- MAGEA1 | c.262C>G p.P88A | Missense Mutation (SNP) | VAF 106/306 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV100756700; called by muse, mutect2, varscan2
- MAGEA3 | c.677G>T p.S226I | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV64756573; called by muse, mutect2, varscan2
- MAK | c.176A>G p.H59R | Missense Mutation (SNP) | VAF 141/464 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157354118, COSV57567953; called by muse, mutect2
- MAP1S | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs746545698, COSV60724795; called by muse, mutect2, varscan2
- MAP3K10 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.112); catalogued as rs202232339, COSV53420700; called by muse, mutect2, varscan2
- MAP3K12 | c.1605dup p.S536Lfs*35 | Frame Shift Ins (INS) | VAF 9/28 reads (32%) | catalogued as rs779220145; called by mutect2, varscan2
- MAPK15 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs573414435, COSV62030481; called by muse, mutect2, varscan2
- MAPKAPK2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as rs772956044, COSV54315875; called by muse, mutect2, varscan2
- MAPRE3 | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV51869476; called by muse, mutect2, varscan2
- MARCHF9 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs146323526; called by muse, mutect2, varscan2
- MARCKS | c.980dup p.A328Sfs*14 | Frame Shift Ins (INS) | VAF 20/70 reads (29%) | catalogued as rs770972906; called by mutect2, varscan2
- MARS1 | c.830A>G p.N277S | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV56258994; called by muse, mutect2, varscan2
- MAST1 | c.1765G>A p.G589R | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52255894; called by muse, mutect2, varscan2
- MATN2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757205252, COSV54720171; called by muse, mutect2, varscan2
- MBD5 | c.790A>C p.S264R | Missense Mutation (SNP) | VAF 118/440 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV68699094; called by muse, mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs762648935; called by pindel, varscan2
- MCF2L | c.2558C>T p.A853V (on ENST00000375608; = p.A821V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56182181; called by muse, mutect2, varscan2
- MCOLN1 | c.1222_1224del p.F408del | In Frame Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs797044817; called by pindel, varscan2
- MCPH1 | c.2312del p.P771Qfs*8 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | catalogued as rs1401112399; called by mutect2, pindel, varscan2
- MCU | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760003771, COSV64068621; called by muse, mutect2, varscan2
- MED13 | c.5081A>G p.Y1694C | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67267379; called by muse, mutect2, varscan2
- MED13L | c.5073_5075del p.E1691del | In Frame Del (DEL) | VAF 44/156 reads (28%) | catalogued as rs1375042465; called by pindel, varscan2
- MED14 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 182/632 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV100247697; called by muse, mutect2, varscan2
- MED4 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 86/307 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV51640606; called by muse, mutect2, varscan2
- MEGF8 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as rs922693299, COSV52078406; called by muse, mutect2, varscan2
- MEGF8 | c.4757del p.G1586Dfs*144 (on ENST00000251268 / NM_001271938.2; = p.G1519Dfs*144 on NM_001410.3) | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | catalogued as rs769979815, COSV52091445; called by mutect2, pindel, varscan2
- MELK | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769278274, COSV99975263; called by muse, mutect2, varscan2
- METTL27 | c.15G>T p.E5D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.437); catalogued as rs781956542, COSV52897331; called by muse, mutect2, varscan2
- MFN1 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54942770; called by muse, mutect2, varscan2
- MFN2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52425802; called by muse, mutect2, varscan2
- MIA3 | c.5600C>T p.P1867L | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.397); catalogued as COSV60518526; called by muse, mutect2, varscan2
- MIB1 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs376378881; called by muse, mutect2, varscan2
- MID2 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 84/290 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs747222924, COSV53314641; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | catalogued as rs762448666; called by mutect2, varscan2
- MIP | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV57515562; called by muse, mutect2, varscan2
- MITF | c.1441G>A p.D481N (on ENST00000448226 / NM_006722.3; = p.D381N on NM_000248.4) | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as rs753927745, COSV58836298; called by muse, mutect2, varscan2
- MLLT6 | c.2468G>A p.R823H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs772684935; called by muse, varscan2
- MMP15 | c.1514G>T p.S505I | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54681722; called by muse, mutect2, varscan2
- MOB1B | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.327); catalogued as rs747885745, COSV58675369; called by muse, mutect2, varscan2
- MOB4 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV52097364; called by muse, mutect2, varscan2
- MRC2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1298715571, COSV57637294; called by muse, mutect2, varscan2
- MROH6 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as rs933594227, COSV67340269; called by muse, mutect2, varscan2
- MRPS2 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs762097553, COSV54092388, COSV54094384; called by muse, mutect2, varscan2
- MRPS6 | c.183C>T p.G61= | Splice Region (SNP) | VAF 56/152 reads (37%) | catalogued as rs779997227, COSV62973821; called by muse, mutect2, varscan2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/128 reads (27%) | catalogued as rs768684761; called by mutect2, pindel, varscan2
- MSI1 | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99981758; called by muse, mutect2
- MTFP1 | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV56742442; called by muse, varscan2
- MTHFD2L | c.1033del p.I345Sfs*48 (on ENST00000395759 / NM_001144978.2; = p.I287Sfs*48 on NM_001004346.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 138/462 reads (30%) | catalogued as rs761538540; called by mutect2, pindel, varscan2
- MTREX | c.544A>G p.K182E | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV57930496; called by muse, mutect2, varscan2
- MUC13 | c.264del p.I89* | Frame Shift Del (DEL) | VAF 90/341 reads (26%) | catalogued as COSV60699158; called by mutect2, pindel, varscan2
- MUC16 | c.9134C>T p.P3045L | Missense Mutation (SNP) | VAF 61/247 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); catalogued as COSV67496717; called by muse, mutect2, varscan2
- MUC16 | c.7072C>T p.R2358W | Missense Mutation (SNP) | VAF 224/791 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs372186047, COSV67485774; called by muse, mutect2, varscan2
- MUC17 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV60305308; called by muse, mutect2, varscan2
- MUC5B | c.6751G>A p.A2251T | Missense Mutation (SNP) | VAF 132/421 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as COSV71595819; called by muse, mutect2, varscan2
- MUSK | c.712A>T p.I238F | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV51897768; called by muse, mutect2, varscan2
- MXRA5 | c.8479G>A p.V2827I | Missense Mutation (SNP) | VAF 255/886 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.098); catalogued as rs745493018, COSV54238634; called by muse, mutect2, varscan2
- MXRA5 | c.8396A>G p.H2799R | Missense Mutation (SNP) | VAF 340/1072 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV99479873; called by muse, mutect2, varscan2
- MYBPC3 | c.2338A>G p.I780V | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.006); catalogued as COSV57034232; called by muse, mutect2, varscan2
- MYBPC3 | c.2179G>A p.V727M | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs564378953, COSV57029079; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, varscan2
- MYCBP2 | c.2480G>A p.R827H (on ENST00000357337; = p.R865H on NM_015057.5) | Missense Mutation (SNP) | VAF 288/970 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs540521860, COSV62037723; called by muse, mutect2, varscan2
- MYH1 | c.542C>A p.S181Y | Missense Mutation (SNP) | VAF 101/361 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56855653, COSV56857921; called by muse, mutect2, varscan2
- MYH13 | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs781556558, COSV52844093; called by muse, varscan2
- MYO10 | c.3272A>G p.Y1091C | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as rs1340942002, COSV57030533; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 31/89 reads (35%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO18B | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs1218793100, COSV59150073; called by muse, mutect2, varscan2
- MYO1D | c.2333C>T p.T778M | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1211032232, COSV59024417; called by muse, mutect2, varscan2
- MYO1E | c.2529T>A p.S843R | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV55696041; called by muse, mutect2, varscan2
- MYO5A | c.1037A>G p.D346G | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV62565104; called by muse, varscan2
- MYO7B | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs763504193, COSV67349356; called by muse, mutect2
- MYO9B | c.6049del p.A2017Pfs*36 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | catalogued as rs1325294870, COSV55727808; called by mutect2, pindel
- MYOF | c.5746C>T p.P1916S | Missense Mutation (SNP) | VAF 71/274 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV63711258; called by muse, mutect2, varscan2
- MYORG | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV99898905; called by muse, mutect2, varscan2
- MYPN | c.2200G>T p.A734S | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV62736115, COSV62740210; called by muse, mutect2, varscan2
- N4BP2 | c.4367C>A p.P1456H | Missense Mutation (SNP) | VAF 227/761 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV54707393; called by muse, mutect2, varscan2
- NABP2 | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99907726; called by muse, mutect2
- NAGLU | c.2057T>C p.V686A | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs760257524, COSV99864443; called by muse, mutect2
- NALCN | c.3791C>T p.S1264L | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs968340313, CM142501, COSV51968001; called by muse, mutect2, varscan2
- NAT16 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1307656509, COSV55865746; called by muse, mutect2, varscan2
- NBEA | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.138); catalogued as COSV100075659, COSV59826054; called by muse, mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 43/120 reads (36%) | catalogued as rs763376147; called by mutect2, varscan2
- NCAM2 | c.703T>C p.S235P | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV53106198; called by muse, mutect2, varscan2
- NCAPG2 | c.1020+1G>A p.X340_splice | Splice Site (SNP) | VAF 34/110 reads (31%) | catalogued as COSV51992036; called by muse, mutect2, varscan2
- NCEH1 | c.1159C>T p.H387Y (on ENST00000538775; = p.H347Y on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs749735755, COSV56438625; called by muse, mutect2, varscan2
- NCOA1 | c.2296C>A p.L766M | Missense Mutation (SNP) | VAF 107/323 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV56053862; called by muse, mutect2, varscan2
- NCOR1 | c.3935T>C p.L1312P | Missense Mutation (SNP) | VAF 248/851 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1282251358, COSV51998418; called by muse, mutect2, varscan2
- NDUFB7 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1328479353, COSV53107655, COSV53109297; called by muse, mutect2, varscan2
- NFATC1 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs375266848; called by muse, mutect2, varscan2
- NFE2L1 | c.2237G>A p.G746D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62583836; called by muse, mutect2, varscan2
- NFKBID | c.185G>A p.R62H (on ENST00000396901; = p.R214H on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1338763934, COSV100756553; called by muse, mutect2, varscan2
- NFYC | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as rs1287759241, COSV58127040; called by muse, mutect2, varscan2
- NINL | c.3156G>T p.E1052D | Missense Mutation (SNP) | VAF 134/379 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV54009498; called by muse, mutect2, varscan2
- NKAPL | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV59197300; called by muse, mutect2, varscan2
- NKTR | c.1847dup p.S617Ffs*15 | Frame Shift Ins (INS) | VAF 44/196 reads (22%) | catalogued as rs763440516; called by mutect2, varscan2
- NLRC5 | c.5001G>T p.L1667F | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV52663983; called by muse, mutect2, varscan2
- NLRP1 | c.1748del p.K583Rfs*14 | Frame Shift Del (DEL) | VAF 62/220 reads (28%) | catalogued as COSV52567752; called by mutect2, pindel, varscan2
- NLRP4 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140509890, COSV100016724, COSV56715578; called by muse, mutect2, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs751187638; called by mutect2, varscan2
- NOP2 | c.1511C>T p.A504V (on ENST00000322166 / NM_001258308.2; = p.A500V on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1432601807, COSV59113835; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 38/73 reads (52%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs765756993; called by mutect2, pindel, varscan2
- NOX1 | c.875A>G p.Q292R | Missense Mutation (SNP) | VAF 91/362 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV54196868; called by muse, mutect2
- NOX5 | c.2026A>G p.M676V | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1422638049, COSV52996676; called by muse, mutect2
- NOXO1 | c.178G>A p.A60T (on ENST00000397280 / NM_172168.3; = p.A59T on NM_144603.4) | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1160909438, COSV50191951; called by muse, mutect2, varscan2
- NPAP1 | c.2810G>A p.S937N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as rs761376976, COSV61511791; called by muse, mutect2, varscan2
- NPHP4 | c.3605C>A p.P1202Q | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65398295; called by muse, mutect2, varscan2
- NR0B1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV66764883; called by muse, mutect2, varscan2
- NR1H3 | c.601del p.Q201Kfs*13 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | catalogued as rs779801455; called by mutect2, pindel, varscan2
- NR3C2 | c.2134G>A p.A712T | Missense Mutation (SNP) | VAF 77/222 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs1202370477, COSV60992039; called by muse, mutect2, varscan2
- NR3C2 | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV100679970; called by muse, mutect2, varscan2
- NRXN1 | c.3911T>C p.M1304T | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs1227467459, COSV60524764; called by muse, mutect2
- NRXN2 | c.808del p.A270Pfs*57 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as rs754860965; called by mutect2, varscan2
- NSMF | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.997); catalogued as rs756007746, COSV53007485; called by muse, mutect2, varscan2
- NUDT18 | c.609G>T p.W203C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99249351; called by muse, mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 52/134 reads (39%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUP210L | c.2698G>A p.V900I | Missense Mutation (SNP) | VAF 86/323 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1170901679, COSV55158637; called by muse, mutect2, varscan2
- NUTM2A | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs1299397075, COSV101095785; called by mutect2, varscan2
- NXF1 | c.1739T>C p.M580T | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99586561; called by muse, mutect2
- OAS3 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV57449670; called by muse, mutect2, varscan2
- OBSCN | c.7895T>C p.L2632P | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99486149; called by muse, mutect2
- OBSCN | c.11263G>A p.G3755R | Missense Mutation (SNP) | VAF 84/269 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV99486152; called by muse, mutect2, varscan2
- OBSL1 | c.2036A>G p.H679R | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54730390; called by muse, mutect2
- ODF1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 79/242 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1356919719, COSV53432366, COSV53433697; called by muse, mutect2, varscan2
- OGDH | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391660249, COSV56046312; called by muse, mutect2, varscan2
- OGDHL | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.371); catalogued as COSV65104896; called by muse, mutect2, varscan2
- OGDHL | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs756698692, COSV65104010; called by muse, mutect2, varscan2
- OR10S1 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771347462, COSV73342706; called by muse, mutect2, varscan2
- OR11H1 | c.681A>C p.K227N | Missense Mutation (SNP) | VAF 264/853 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV99422081; called by muse, varscan2
- OR1D2 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 102/307 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV58922588; called by muse, mutect2, varscan2
- OR1J4 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.02); catalogued as COSV61590402; called by muse, mutect2, varscan2
- OR2L2 | c.860T>A p.I287N | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV63561911; called by muse, mutect2, varscan2
- OR2T10 | c.875T>G p.F292C | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV57898553; called by muse, mutect2, varscan2
- OR2T27 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754542022, COSV100788448; called by muse, mutect2, varscan2
- OR4C15 | c.988A>G p.I330V (on ENST00000314644; = p.I276V on NM_001001920.2) | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.03); catalogued as COSV58955985; called by muse, varscan2
- OR4C46 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 90/287 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60221402; called by muse, mutect2, varscan2
- OR4K2 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 115/697 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV100064468, COSV100064835; called by muse, mutect2, varscan2
- OR5AU1 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV58616283; called by muse, mutect2, varscan2
- OR5H14 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 118/1578 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV101454343, COSV71193561; called by muse, mutect2
- OR7D2 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV60140424, COSV60141504; called by muse, mutect2, varscan2
- OSBPL5 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs907431268, COSV55140090; called by muse, mutect2, varscan2
- OXER1 | c.499G>T p.V167F | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); catalogued as COSV54313330; called by muse, mutect2, varscan2
- P3H3 | c.1164G>T p.R388S | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV99301829; called by muse, mutect2, varscan2
- PACS2 | c.1906C>T p.R636C | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782754114, COSV57657638; called by muse, mutect2, varscan2
- PALD1 | c.2389C>T p.Q797* | Nonsense Mutation (SNP) | VAF 35/135 reads (26%) | catalogued as COSV99698801; called by muse, mutect2, varscan2
- PAPOLA | c.675A>T p.R225S | Missense Mutation (SNP) | VAF 82/363 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53485900; called by muse, mutect2, varscan2
- PARD3B | c.1382C>G p.T461R | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375783598; called by muse, mutect2, varscan2
- PARM1 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV56660317; called by muse, mutect2, varscan2
- PARP10 | c.2556T>C p.R852= | Splice Region (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100478445; called by muse, mutect2
- PARP14 | c.4720C>T p.R1574W | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV71734796; called by muse, mutect2, varscan2
- PATJ | c.3347C>T p.T1116M | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777907543, COSV57175105; called by muse, mutect2, varscan2
- PBRM1 | c.835del p.I279Yfs*4 | Frame Shift Del (DEL) | VAF 35/125 reads (28%) | catalogued as rs771618422; called by mutect2, pindel, varscan2
- PCDH10 | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52104696; called by muse, mutect2, varscan2
- PCDH17 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV64979939; called by muse, mutect2, varscan2
- PCDH17 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV64979943; called by muse, mutect2, varscan2
- PCDH19 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.894); catalogued as COSV55272206; called by muse, mutect2
- PCDH7 | c.1801C>T p.Q601* | Nonsense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as COSV62343922; called by muse, mutect2, varscan2
- PCDHA12 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV56497769; called by muse, mutect2, varscan2
- PCDHA5 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.034); catalogued as COSV65352881; called by muse, mutect2, varscan2
- PCDHB10 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.331); catalogued as COSV99504320; called by muse, varscan2
- PCDHGA11 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs754599902, COSV54005887; called by muse, mutect2, varscan2
- PCDHGA11 | c.2170del p.R724Afs*19 | Frame Shift Del (DEL) | VAF 40/145 reads (28%) | catalogued as COSV54042009, COSV99542652; called by mutect2, pindel, varscan2
- PCDHGA8 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.044); catalogued as rs1474626800, COSV54036321; called by muse, mutect2, varscan2
- PCNT | c.7189C>T p.Q2397* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as rs776734492, COSV100856193; called by muse, mutect2, varscan2
- PCNX2 | c.1856del p.K619Rfs*52 | Frame Shift Del (DEL) | VAF 160/683 reads (23%) | catalogued as COSV50784264; called by mutect2, pindel, varscan2
- PCP2 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99657498; called by muse, varscan2
- PDCD1 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV57692311; called by muse, mutect2, varscan2
- PDCD11 | c.2735A>G p.Q912R | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100874443; called by muse, mutect2, varscan2
- PDE4D | c.506T>C p.M169T (on ENST00000340635 / NM_001104631.2; = p.M33T on NM_006203.4) | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.19); catalogued as COSV58982431; called by muse, mutect2
- PDE6B | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs145863444; called by muse, mutect2, varscan2
- PDGFRB | c.3034G>A p.V1012M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as rs757545741, COSV53833936, COSV53844019; called by muse, mutect2, varscan2
- PDHA2 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs763063009, COSV54778891, COSV99756713, COSV99757008; called by muse, mutect2, varscan2
- PDZD7 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368583838, COSV64647706; called by muse, mutect2, varscan2
- PDZRN3 | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1219414725, COSV99732877; called by muse, mutect2, varscan2
- PDZRN3 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1368215350, COSV55216579; called by muse, mutect2, varscan2
- PDZRN4 | c.2204G>T p.S735I (on ENST00000402685 / NM_001164595.2; = p.S477I on NM_013377.4) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54218419; called by muse, mutect2, varscan2
- PEDS1 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1433817654, COSV59016569; called by muse, mutect2, varscan2
- PENK | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152531; called by muse, mutect2, varscan2
- PEPD | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765552774, COSV52287028; called by muse, mutect2, varscan2
- PFKL | c.2284G>A p.V762M | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs766957279, COSV100297233; called by muse, mutect2, varscan2
- PGAP6 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51742846; called by muse, mutect2, varscan2
- PGAP6 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs745477438, COSV51742856; called by muse, mutect2, varscan2
- PGM3 | c.499T>C p.Y167H | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.544); catalogued as COSV52286177; called by muse, mutect2, varscan2
- PGS1 | c.1270del p.V424Wfs*60 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | catalogued as COSV53143184; called by mutect2, pindel, varscan2
- PHC1 | c.2256G>T p.V752= | Splice Region (SNP) | VAF 28/109 reads (26%) | catalogued as COSV70418781; called by muse, mutect2, varscan2
- PHEX | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs761575825, COSV65078177, COSV65079370; ClinVar: likely benign; called by muse, mutect2, varscan2
- PHF13 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50011887; called by muse, mutect2, varscan2
- PHF21A | c.1955del p.P652Lfs*104 (on ENST00000418153 / NM_001101802.3; = p.P606Lfs*104 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 32/103 reads (31%) | catalogued as rs761575760; called by mutect2, pindel, varscan2
- PI16 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as rs780503142, COSV65448805; called by muse, mutect2, varscan2
- PI4KA | c.5386C>T p.Q1796* | Nonsense Mutation (SNP) | VAF 72/233 reads (31%) | catalogued as rs62619942, COSV55424326; called by muse, mutect2, varscan2
- PI4KB | c.608G>A p.R203H (on ENST00000368873 / NM_001369623.1; = p.R215H on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs766903450, COSV55017195, COSV55022007; called by muse, mutect2, varscan2
- PIF1 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as rs200699011, COSV99164731; called by muse, mutect2, varscan2
- PIF1 | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.455); catalogued as COSV51424757, COSV99165241; called by muse, mutect2, varscan2
- PIGA | c.1139T>C p.I380T | Missense Mutation (SNP) | VAF 239/770 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs768749706, COSV61238541; called by muse, mutect2, varscan2
- PIK3C2A | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 50/162 reads (31%) | catalogued as COSV56402573; called by muse, mutect2, varscan2
- PKDREJ | c.4544C>T p.A1515V | Missense Mutation (SNP) | VAF 224/694 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV53553523; called by muse, varscan2
- PKHD1 | c.7378A>C p.K2460Q | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as COSV100584285, COSV61896313; called by muse, mutect2, varscan2
- PKN2 | c.232del p.S78Vfs*5 | Frame Shift Del (DEL) | VAF 81/288 reads (28%) | catalogued as rs1335792632, COSV60133695; called by mutect2, pindel, varscan2
- PKN3 | c.983-2A>G p.X328_splice | Splice Site (SNP) | VAF 74/223 reads (33%) | catalogued as COSV52579992; called by muse, mutect2, varscan2
- PLA2G4F | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs149401636; called by muse, mutect2, varscan2
- PLCB2 | c.1778T>C p.V593A | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53038452; called by muse, mutect2
- PLCB3 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs760695903, COSV54192626; called by muse, mutect2, varscan2
- PLEKHB1 | c.543dup p.N182Qfs*102 | Frame Shift Ins (INS) | VAF 13/64 reads (20%) | catalogued as rs747647640; called by mutect2, pindel, varscan2
- PLEKHG4B | c.602G>A p.G201E (on ENST00000283426; = p.G557E on NM_052909.5) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV52055838; called by muse, mutect2, varscan2
989 further variants in this file (557 protein-altering or splice-affecting, 392 silent, 40 other) are not listed here.
